Surgical pathology report (de-identified scan), TCGA case TCGA-FN-7833, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site International Genomics Consortium, specimen TCGA-FN-7833-01A (Primary Tumor).

[page 1 of 2]
FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

- A. -B.) RIGHT FRONTAL LOBE OF BRAIN, TUMOR RESECTION:
- ANAPLASTIC OLIGOASTROCYTOMA (WHO GRADE III).
- SEE COMMENT.

COMMENT: This case was submitted for consultation to the Department of Neuropathology at the [REDACTED] where it was reviewed by [REDACTED]. The diagnosis rendered at [REDACTED] is reflected above. The tumor was found to have intact 1p and 19q. See separate neuropathology consultation report from [REDACTED]. The preliminary pathology findings were discussed with [REDACTED].

[REDACTED]

Source of Specimen:

- A. Right Frontal Mass/Tumor
- B. Right Frontal Tumor

Clinical History/Operative Dx:

Right frontal intracerebral mass

Intraoperative Diagnosis:

A. FSA: Gliosis vs low grade glioma; no evidence of high grade glial neoplasm identified. [REDACTED]

Performed at [REDACTED]

Gross Description:

A. Part A designated right frontal mass/tumor. Received in a fresh state for frozen section analysis is a 1.8 x 1.3 x 0.9 cm single light gray fragment of delicate soft tissue. A representative section is submitted for frozen section analysis and three touch preparation slides are forwarded for staining, followed by

[REDACTED]

[page 2 of 2]
FINAL SURGICAL PATHOLOGY REPORT

microscopic evaluation. The residual frozen tissue submitted in A1 for permanent sections, and the remainder of the soft tissue is submitted in A2 for routine histology

B. Part B is right frontal tumor. Initially received in a fresh state for tumor bank studies, are multiple fragments of delicate light gray and fleshy pink-gray soft tissue, measuring in aggregate of 36 grams and 7.2 x 6.8 x 2.4 cm. The surfaces of the larger intact pieces, demonstrate translucent, slightly hyperemic meninges. Upon sectioning the gray matter is partially well delineated and serpiginous, however, it is obscured in several of the fragments, grossly attributed to a fleshy, pink-gray mass lesion. Portions of grossly viable tumor are submitted for tumor bank studies. Representative sections are submitted for microscopic evaluation in B1-B10 (nineteen pieces). (IJ) Following initial microscopic evaluation the remainder of the brain tissue is entirely submitted for microscopic evaluation in B11-B24.

Microscopic Description:

A. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

B. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

Source: NCI Genomic Data Commons file ddc83ead-f4ec-41fc-886f-c07d343fcc96 (TCGA-FN-7833.A6B649B5-CF85-4F4E-BF5F-4870A16C1F93.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).